Somatic mutation profile of tumor specimen MMRF_1171_1_BM_CD138pos (aliquot MMRF_1171_1_BM_CD138pos_T1_KAS5U_L00336) from MMRF case MMRF_1171, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 36.4 years (13,280 days).
Specimen MMRF_1171_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d43cd90-80b4-4052-a351-66ad1bd247c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1171_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1171_1_PB_Whole_C2_KAS5U_L00337; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5208efdd-54a7-4400-9d19-d74e02311a52

The open-access MAF lists 66 somatic variants for this specimen: 28 protein-altering or splice-affecting, 12 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, 3'UTR 15, Silent 12, Intron 7, Splice Site 2, Nonsense Mutation 1, RNA 1, 3'Flank 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM1 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.362); catalogued as rs200432876, COSV99521461; called by muse, mutect2, varscan2
- ADAM12 | c.1847G>A p.R616Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs768660681, COSV64104510, COSV64107064, COSV64108168; called by muse, mutect2, varscan2
- COL21A1 | c.2036C>T p.T679M | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs371094018; called by muse, mutect2, varscan2
- DNAH5 | c.4960C>T p.R1654W | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs139364454; called by muse, varscan2
- IGHV1-69 | c.163T>C p.W55R | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as rs879983155; called by muse, mutect2, varscan2
- IGHV2-70 | c.243C>A p.S81R | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs368831727; called by muse, varscan2
- IGLL5 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.087); catalogued as rs777349722, COSV73249535, COSV73250343, COSV73250409; called by muse, mutect2, varscan2
- KMT2E | c.2030T>C p.I677T | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); catalogued as rs1362475451; called by muse, mutect2
- LRCH3 | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs761841360; called by muse, mutect2, varscan2
- POLR2H | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as rs766498153, COSV55599728; called by muse, mutect2, varscan2
- SERPINA4 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs540841872, COSV54069263; called by muse, mutect2, varscan2
- TTBK1 | c.2098C>T p.R700W | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as rs370022725, COSV52488871, COSV52492583; called by muse, varscan2
- AK5 | c.296C>A p.P99H (on ENST00000354567 / NM_174858.3; = p.P73H on NM_012093.4) | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BTG1 | c.107A>T p.Q36L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CNTN1 | c.2537C>A p.A846D | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.184); called by muse, mutect2
- HIPK1 | c.266C>A p.A89D | Missense Mutation (SNP) | VAF 77/139 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- HSD11B1L | c.725A>G p.Q242R | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSD17B4 | c.830C>G p.T277S (on ENST00000414835 / NM_001199291.3; = p.T252S on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.94); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MINAR1 | c.204G>T p.K68N | Missense Mutation (SNP) | VAF 164/235 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PCF11 | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PKHD1 | c.12055C>A p.L4019M | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PPIP5K1 | c.4130A>G p.E1377G (on ENST00000396923; = p.E1352G on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- SEC31B | c.3446C>G p.A1149G | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- SETD4 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SLC38A4 | c.1073+2T>C p.X358_splice | Splice Site (SNP) | VAF 60/145 reads (41%) | called by muse, mutect2, varscan2
- SOWAHC | c.1388G>C p.S463T | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.272); called by muse, mutect2
- SYNE2 | c.19334-2A>G p.X6445_splice | Splice Site (SNP) | VAF 54/124 reads (44%) | called by muse, mutect2, varscan2
- SYNPO2 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2
- BCAM | c.1296G>A p.P432= | Silent (SNP) | VAF 53/146 reads (36%) | catalogued as rs757677631, COSV54302587; called by muse, mutect2, varscan2
- BTG1 | c.108G>A p.Q36= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs533912735, COSV55457953, COSV55458217, COSV55458575; called by muse, mutect2, varscan2
- DDX60 | c.1164T>C p.Y388= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- EPHA8 | c.318C>T p.R106= | Silent (SNP) | VAF 7/179 reads (4%) | catalogued as rs1275281000, COSV51263927; called by muse, mutect2
- EZH2 | c.1884C>T p.I628= (on ENST00000460911 / NM_001203247.2; = p.I633= on NM_004456.5) | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV57463913; called by muse, mutect2, varscan2
- GPR108 | c.630G>T p.V210= | Silent (SNP) | VAF 31/90 reads (34%) | called by muse, mutect2, varscan2
- MAJIN | c.27G>A p.P9= | Silent (SNP) | VAF 75/272 reads (28%) | catalogued as rs142880411; called by muse, mutect2, varscan2
- PRLR | c.681T>C p.P227= | Silent (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
- ST3GAL2 | c.966G>A p.K322= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV61596745; called by muse, mutect2, varscan2
- UNC13B | c.279T>C p.P93= | Silent (SNP) | VAF 79/135 reads (59%) | called by muse, mutect2, varscan2
- VIT | c.1362C>T p.N454= (on ENST00000389975 / NM_001177969.1; = p.N469= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs1246729509, COSV64896300; called by muse, mutect2
- VSIG10L | c.1158C>T p.H386= | Silent (SNP) | VAF 51/78 reads (65%) | catalogued as rs1205532780; called by muse, mutect2, varscan2
- ANO3 | c.*872C>A | 3'UTR (SNP) | VAF 36/93 reads (39%) | called by muse, mutect2, varscan2
- BCAT1 | c.*141_*144del | 3'UTR (DEL) | VAF 8/98 reads (8%) | called by mutect2, pindel
- CLN8 | c.*2733C>T | 3'UTR (SNP) | VAF 30/54 reads (56%) | called by muse, mutect2, varscan2
- COL6A2 | c.*211T>C | 3'UTR (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
- CPNE7 | c.1764+309G>A | Intron (SNP) | VAF 24/50 reads (48%) | catalogued as rs1036328958, COSV99254990; called by muse, mutect2, varscan2
- DGKB | c.*3194C>T | 3'UTR (SNP) | VAF 35/64 reads (55%) | catalogued as rs539537722; called by muse, mutect2, varscan2
- DLL1 | c.*159C>T | 3'UTR (SNP) | VAF 7/38 reads (18%) | catalogued as rs574425432; called by muse, mutect2, varscan2
- ERRFI1 | c.*243G>T | 3'UTR (SNP) | VAF 38/79 reads (48%) | called by muse, mutect2, varscan2
- ESYT3 | c.915+20C>T | Intron (SNP) | VAF 20/43 reads (47%) | catalogued as rs748280851; called by muse, mutect2, varscan2
- FMOD | c.*595C>T | 3'UTR (SNP) | VAF 31/68 reads (46%) | called by muse, mutect2, varscan2
- GSTM5 | c.568-803G>A | Intron (SNP) | VAF 44/83 reads (53%) | called by muse, mutect2, varscan2
- KCNAB2 | c.1014+262C>T | Intron (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- KCNJ5 | chr11:128919080 C>T | 3'Flank (SNP) | VAF 30/120 reads (25%) | called by muse, mutect2, varscan2
- KLHL12 | c.*226A>G | 3'UTR (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- MBL3P | n.347C>A | RNA (SNP) | VAF 24/55 reads (44%) | called by muse, mutect2, varscan2
- METRN | c.506-282C>G | Intron (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851311 G>A | 5'Flank (SNP) | VAF 43/98 reads (44%) | catalogued as rs769465513; called by muse, mutect2, varscan2
- NELL2 | c.-398dup | 5'UTR (INS) | VAF 37/78 reads (47%) | catalogued as rs1190606999; called by mutect2, varscan2
- NKX6-1 | c.*569T>C | 3'UTR (SNP) | VAF 28/55 reads (51%) | called by muse, mutect2, varscan2
- PIGR | c.*17C>T | 3'UTR (SNP) | VAF 46/75 reads (61%) | called by muse, mutect2, varscan2
- SEL1L | c.*2726_*2727insC | 3'UTR (INS) | VAF 7/69 reads (10%) | called by pindel, varscan2*
- SLC12A1 | c.629-770C>A | Intron (SNP) | VAF 27/103 reads (26%) | called by muse, mutect2, varscan2
- SOX8 | c.423-41G>A | Intron (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2
- SRRM4 | c.*5858del | 3'UTR (DEL) | VAF 34/74 reads (46%) | catalogued as rs1055733872; called by mutect2, varscan2
- STAT6 | c.*537T>G | 3'UTR (SNP) | VAF 4/98 reads (4%) | called by muse, mutect2
- ZNF438 | c.*25G>A | 3'UTR (SNP) | VAF 4/36 reads (11%) | catalogued as rs1378117068; called by muse, mutect2
